Somatic mutation profile of tumor specimen MBCProject_0281_T1_WES (aliquot MBCProject_0281_T1_WES_1) from CMI case MBCProject_0281, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0281_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e74a2fd8-a0f5-428b-a7ff-3fc54f6370c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0281_SALIVA (Saliva), aliquot MBCProject_0281_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe71cd19-ba04-4bba-bca9-4394d1bd5b01

The open-access MAF lists 63 somatic variants for this specimen: 50 protein-altering or splice-affecting, 2 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Intron 4, 3'UTR 3, 5'UTR 2, Silent 2, Splice Region 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.5451G>A p.L1817= (on ENST00000614293; = p.L1787= on NM_001606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/76 reads (24%) | catalogued as COSV55806684; called by muse, mutect2, varscan2
- CHD2 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs543203414, COSV67709302; called by muse, mutect2, varscan2
- FLG2 | c.3937A>G p.T1313A | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV101166350; called by muse, mutect2
- GRID2 | c.2701G>A p.D901N | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56207962; called by muse, mutect2, varscan2
- MEGF10 | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758447348, COSV57248431; called by muse, mutect2, varscan2
- NPR1 | c.1471T>A p.F491I | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100902047; called by muse, mutect2, varscan2
- OPRK1 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV55569536; called by muse, mutect2, varscan2
- PLD1 | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768898754, COSV60570125; called by muse, mutect2
- STAB2 | c.1851G>C p.Q617H | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1027430385; called by muse, mutect2, varscan2
- TVP23A | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs762295494; called by muse, mutect2, varscan2
- UNK | c.2429C>T p.S810L | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772068812; called by muse, mutect2
- WNT2 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1327137009; called by muse, mutect2, varscan2
- WTIP | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV99542533; called by muse, mutect2, varscan2
- ZNF16 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 104/494 reads (21%) | catalogued as rs761644689; called by muse, mutect2, varscan2
- ADAM10 | c.1724A>T p.Y575F | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AK9 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ASTN1 | c.3474C>A p.D1158E | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CA4 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 101/864 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CERCAM | c.1658C>G p.S553C | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CMYA5 | c.10573A>G p.K3525E | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CUBN | c.4537A>T p.I1513F | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- DCBLD2 | c.1691C>G p.T564S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ESPL1 | c.3851C>A p.T1284N | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- EZH1 | c.1395C>G p.C465W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- F8 | c.1362_1379del p.F455_A460del | In Frame Del (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- FAT4 | c.7838C>A p.T2613N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- FCRL3 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLNA | c.6539G>C p.S2180T (on ENST00000369850 / NM_001110556.2; = p.S2172T on NM_001456.3) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GK3P | c.1606A>G p.I536V | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLA | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 183/710 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- HOMER3 | c.358T>G p.S120A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- HOXA7 | c.235A>C p.N79H | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- KIAA1522 | c.2380G>T p.A794S (on ENST00000373480 / NM_001198972.2; = p.A853S on NM_020888.3) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MAGEB6B | c.966T>A p.H322Q | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAT5B | c.1419G>C p.W473C | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFKBIZ | c.726dup p.V243Rfs*81 | Frame Shift Ins (INS) | VAF 66/325 reads (20%) | called by mutect2, pindel, varscan2
- PLEKHF1 | c.374A>C p.H125P | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PROM2 | c.1830G>T p.Q610H | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PTPN7 | c.188C>G p.S63C (on ENST00000495688; = p.S102C on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2
- RAD51 | c.465_469del p.K156Hfs*4 | Frame Shift Del (DEL) | VAF 46/194 reads (24%) | called by mutect2, pindel, varscan2
- RYR2 | c.6929-1G>A p.X2310_splice | Splice Site (SNP) | VAF 30/237 reads (13%) | called by muse, mutect2, varscan2
- SAT1 | c.372_382del p.M125Gfs*6 | Frame Shift Del (DEL) | VAF 36/77 reads (47%) | called by mutect2, pindel*, varscan2*
- SEC16B | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 65/380 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHARPIN | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCHP | c.189C>T p.S63= | Splice Region (SNP) | VAF 36/143 reads (25%) | called by muse, mutect2, varscan2
- TMEM132E | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.992); called by muse, mutect2
- USP35 | c.1310A>G p.D437G | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- XAF1 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNF704 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 143/443 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF804B | c.3136G>C p.A1046P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM19 | c.516A>C p.G172= | Silent (SNP) | VAF 51/236 reads (22%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1668G>A p.E556= | Silent (SNP) | VAF 32/111 reads (29%) | called by muse, varscan2
- AC024940.1 | n.2256A>G | RNA (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- CAVIN1 | c.*17C>T | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*345C>T | 3'UTR (SNP) | VAF 76/202 reads (38%) | called by muse, mutect2, varscan2
- COG5 | c.-31T>G | 5'UTR (SNP) | VAF 111/500 reads (22%) | called by muse, mutect2, varscan2
- IFI44 | c.*11G>T | 3'UTR (SNP) | VAF 13/97 reads (13%) | catalogued as rs1299059075; called by muse, mutect2, varscan2
- MARCHF6 | c.-37G>A | 5'UTR (SNP) | VAF 26/560 reads (5%) | called by muse, mutect2
- PIK3CD | c.-138+2542C>G | Intron (SNP) | VAF 130/568 reads (23%) | catalogued as rs571688560; called by muse, mutect2, varscan2
- PLPP5 | c.635-383G>A | Intron (SNP) | VAF 23/132 reads (17%) | catalogued as rs72644712; called by muse, mutect2, varscan2
- SLC22A7 | c.399+129T>A | Intron (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | chr12:21092574 del T | 3'Flank (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- VAC14 | c.1371+7292T>A | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
